Somatic mutation profile of tumor specimen 0DW42C from CCDI case PBCHHJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 20.9 years (7,643 days).
Specimen 0DW42C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2df4985c-bad0-40d9-8a39-7cc212cf570e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DW41D (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f233e03e-d688-447a-ab40-2e0e552824ae

The open-access MAF lists 78 somatic variants for this specimen: 49 protein-altering or splice-affecting, 16 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 16, Nonsense Mutation 8, Intron 6, 3'UTR 5, Splice Region 2, 5'UTR 2, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC3 | c.2527G>A p.G843S | Missense Mutation (SNP) | VAF 30/294 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as rs759454160, COSV53321951; called by muse, mutect2
- ADAMTS17 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs1264294955; called by muse, mutect2, varscan2
- APOB | c.12677C>T p.T4226M | Missense Mutation (SNP) | VAF 221/511 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs371177562, COSV51949085; called by muse, mutect2, varscan2
- ARMC5 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 109/258 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs539440145, COSV51657250; called by muse, mutect2, varscan2
- CPED1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 75/1306 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs781464866; called by muse, mutect2
- GPR150 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 89/225 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101187390; called by muse, mutect2, varscan2
- HDAC4 | c.1296C>T p.G432= | Splice Region (SNP) | VAF 99/223 reads (44%) | catalogued as COSV61869525; called by muse, mutect2, varscan2
- KCNH5 | c.2437C>T p.R813* | Nonsense Mutation (SNP) | VAF 284/577 reads (49%) | catalogued as rs1479096784; called by muse, mutect2, varscan2
- KIF14 | c.1367C>T p.T456M | Missense Mutation (SNP) | VAF 174/466 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66259647; called by muse, mutect2, varscan2
- KSR2 | c.1940G>A p.R647H | Missense Mutation (SNP) | VAF 147/507 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772271177; called by muse, mutect2, varscan2
- MUC12 | c.2456G>A p.R819H (on ENST00000379442; = p.R676H on NM_001164462.1) | Missense Mutation (SNP) | VAF 103/1090 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.517); catalogued as rs759924226; called by muse, mutect2
- MUC16 | c.29779C>A p.Q9927K | Missense Mutation (SNP) | VAF 64/434 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.159); catalogued as COSV67445600; called by muse, mutect2, varscan2
- NALCN | c.4634G>A p.R1545Q | Missense Mutation (SNP) | VAF 217/855 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99216458; called by muse, mutect2, varscan2
- NCKAP1L | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 276/1053 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1218763304, COSV53203993; called by muse, mutect2, varscan2
- NLRP4 | c.715G>A p.G239S | Missense Mutation (SNP) | VAF 86/499 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.088); catalogued as rs757818979; called by muse, mutect2, varscan2
- PIH1D2 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 142/158 reads (90%) | catalogued as rs1047974964; called by muse, mutect2, varscan2
- POSTN | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 301/1283 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753830117, COSV65714455; called by muse, mutect2, varscan2
- POU3F2 | c.237_257del p.G82_G88del | In Frame Del (DEL) | VAF 69/174 reads (40%) | catalogued as rs911869813; called by mutect2, varscan2
- RGS12 | c.3805G>A p.D1269N | Missense Mutation (SNP) | VAF 76/163 reads (47%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.015); catalogued as rs757182071; called by muse, mutect2, varscan2
- RHBDD2 | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 175/957 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs782132146; called by muse, mutect2, varscan2
- RUNDC3A | c.1234G>A p.G412S | Missense Mutation (SNP) | VAF 286/578 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs773884491; called by muse, mutect2, varscan2
- SEMA3E | c.1207C>T p.R403* | Nonsense Mutation (SNP) | VAF 194/1005 reads (19%) | catalogued as rs763314856; called by muse, mutect2, varscan2
- SFRP4 | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 139/828 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as rs201281505; called by muse, mutect2, varscan2
- WIPF2 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 127/248 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs771441782; called by muse, varscan2
- ZNF853 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs1303488580, COSV101499522; called by muse, mutect2, varscan2
- ZP1 | c.1510C>T p.R504* | Nonsense Mutation (SNP) | VAF 17/546 reads (3%) | catalogued as rs1264020643; called by muse, mutect2
- ZSWIM5 | c.2665C>T p.R889* | Nonsense Mutation (SNP) | VAF 201/670 reads (30%) | catalogued as rs1215454122; called by muse, mutect2, varscan2
- ABCB9 | c.1140C>G p.S380R | Missense Mutation (SNP) | VAF 25/710 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ABHD3 | c.461A>G p.E154G | Missense Mutation (SNP) | VAF 250/513 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- ACRBP | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 85/918 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2
- C5orf34 | c.1721T>C p.L574S | Missense Mutation (SNP) | VAF 206/1201 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CFAP54 | c.4095C>A p.F1365L | Missense Mutation (SNP) | VAF 146/478 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- DNAH12 | c.3202T>G p.W1068G (on ENST00000351747; = p.W1091G on NM_001366028.2) | Missense Mutation (SNP) | VAF 310/667 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DOP1A | c.104C>A p.A35E | Missense Mutation (SNP) | VAF 204/749 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EYS | c.3288G>T p.K1096N | Missense Mutation (SNP) | VAF 212/753 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- GOSR1 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 122/329 reads (37%) | called by muse, mutect2, varscan2
- LRP1B | c.2968+2C>A p.X990_splice | Splice Site (SNP) | VAF 200/668 reads (30%) | called by muse, mutect2, varscan2
- PHTF1 | c.1554T>A p.C518* | Nonsense Mutation (SNP) | VAF 273/656 reads (42%) | called by muse, mutect2, varscan2
- PTPRN | c.2622C>A p.S874R | Missense Mutation (SNP) | VAF 123/257 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- PYGO1 | c.104C>A p.P35Q | Missense Mutation (SNP) | VAF 238/473 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLCO1B3 | c.225T>C p.I75= | Splice Region (SNP) | VAF 107/427 reads (25%) | called by muse, mutect2, varscan2
- TCP10L2 | c.157C>A p.Q53K | Missense Mutation (SNP) | VAF 54/319 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- TG | c.2890C>T p.R964W | Missense Mutation (SNP) | VAF 101/389 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, varscan2
- TNFSF10 | c.688T>G p.C230G | Missense Mutation (SNP) | VAF 180/969 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNN | c.149T>C p.V50A | Missense Mutation (SNP) | VAF 200/585 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- TPT1 | c.113G>T p.R38M | Missense Mutation (SNP) | VAF 159/716 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- UNC13C | c.6340T>A p.Y2114N | Missense Mutation (SNP) | VAF 171/366 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VCAM1 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 243/539 reads (45%) | called by muse, mutect2, varscan2
- ZSCAN5B | c.239A>G p.K80R | Missense Mutation (SNP) | VAF 124/975 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CHTF18 | c.396G>A p.P132= | Silent (SNP) | VAF 145/344 reads (42%) | catalogued as rs747132470; called by muse, mutect2, varscan2
- COLGALT1 | c.693T>G p.V231= | Silent (SNP) | VAF 237/744 reads (32%) | catalogued as rs752732959; called by muse, mutect2, varscan2
- DHRS1 | c.498C>A p.G166= | Silent (SNP) | VAF 128/272 reads (47%) | called by muse, mutect2, varscan2
- EXOC8 | c.1803T>C p.F601= | Silent (SNP) | VAF 161/524 reads (31%) | called by muse, mutect2, varscan2
- FRAS1 | c.11973T>C p.A3991= | Silent (SNP) | VAF 269/627 reads (43%) | called by muse, mutect2, varscan2
- GPT | c.627C>T p.D209= | Silent (SNP) | VAF 133/253 reads (53%) | catalogued as rs762385509; called by muse, mutect2, varscan2
- LOXL2 | c.684C>G p.R228= | Silent (SNP) | VAF 377/881 reads (43%) | called by muse, mutect2, varscan2
- OR4Q3 | c.426T>C p.L142= | Silent (SNP) | VAF 73/339 reads (22%) | called by muse, mutect2, varscan2
- PNPLA2 | c.408C>T p.D136= | Silent (SNP) | VAF 164/345 reads (48%) | catalogued as rs371125971; called by muse, mutect2, varscan2
- RNF208 | c.390G>A p.S130= | Silent (SNP) | VAF 76/154 reads (49%) | catalogued as rs1001341160, COSV100763114; called by muse, mutect2, varscan2
- SH2D5 | c.867C>T p.G289= (on ENST00000444387 / NM_001103161.2; = p.G205= on NM_001103160.2) | Silent (SNP) | VAF 109/370 reads (29%) | called by muse, mutect2, varscan2
- SLC9A2 | c.1575T>C p.F525= | Silent (SNP) | VAF 243/912 reads (27%) | catalogued as rs768220637; called by muse, mutect2, varscan2
- TP53I11 | c.420C>T p.F140= | Silent (SNP) | VAF 148/318 reads (47%) | catalogued as rs778453087, COSV57534088; called by muse, mutect2, varscan2
- VPS37D | c.555G>A p.S185= | Silent (SNP) | VAF 73/305 reads (24%) | catalogued as rs782153554, COSV100265334; called by muse, mutect2, varscan2
- ZNF469 | c.5493G>T p.P1831= (on ENST00000437464; = p.P1859= on NM_001367624.2) | Silent (SNP) | VAF 68/152 reads (45%) | called by mutect2, varscan2
- ZNF608 | c.3450G>A p.S1150= | Silent (SNP) | VAF 159/306 reads (52%) | catalogued as rs189382479; called by muse, mutect2, varscan2
- ACADL | c.*41G>A | 3'UTR (SNP) | VAF 74/165 reads (45%) | catalogued as rs370932848; called by muse, mutect2, varscan2
- ADCY1 | c.1605+2199G>T | Intron (SNP) | VAF 49/282 reads (17%) | called by muse, mutect2
- AQP1 | c.385-508C>T | Intron (SNP) | VAF 24/131 reads (18%) | catalogued as rs745336730; called by muse, mutect2, varscan2
- BOC | c.-68A>G | 5'UTR (SNP) | VAF 63/142 reads (44%) | called by muse, mutect2, varscan2
- C5orf22 | c.*82G>C | 3'UTR (SNP) | VAF 47/307 reads (15%) | called by muse, mutect2, varscan2
- CACNA1I | c.*38G>A | 3'UTR (SNP) | VAF 58/126 reads (46%) | catalogued as rs1002699037; called by muse, mutect2, varscan2
- DIS3L2 | c.2395-57G>A | Intron (SNP) | VAF 18/27 reads (67%) | called by muse, mutect2, varscan2
- EIF3F | c.*610A>G | 3'UTR (SNP) | VAF 92/193 reads (48%) | called by muse, mutect2, varscan2
- KLHL42 | c.1066+52C>A | Intron (SNP) | VAF 69/188 reads (37%) | called by muse, mutect2, varscan2
- KSR2 | c.1687+66G>A | Intron (SNP) | VAF 63/211 reads (30%) | called by muse, mutect2, varscan2
- LMF2 | c.1158-22G>A | Intron (SNP) | VAF 67/148 reads (45%) | catalogued as rs375153348; called by muse, mutect2, varscan2
- MDN1 | c.-12G>A | 5'UTR (SNP) | VAF 38/135 reads (28%) | called by muse, mutect2, varscan2
- TBL3 | c.*1079C>T | 3'UTR (SNP) | VAF 53/92 reads (58%) | called by muse, mutect2, varscan2
